Surgical pathology report (de-identified scan), TCGA case TCGA-57-1994, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1994-01A (Primary Tumor).

[page 1 of 3]
COMMENTS:

Although the small deposit of neoplasm in the endometrium does not show distinct papillary growth features, cytologically it is essentially identical to the neoplasm seen in the ovaries. Similarly, the neoplasm in the parametrial soft tissues does not show distinct papillary growth pattern but is cytologically similar to the ovarian neoplasm.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left tube and ovary FS
- B. Pelvic nodules
- C. Uterus, right tube and ovary
- D. Left pelvic nodes
- E. Left para-aortic
- F. Left pelvic
- G. Right pelvic
- H. Right para-aortic
- I. Omentum
- Umbilical hernia

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is labeled [redacted] and consists of a 179 gram tan-gray hemorrhagic ovarian mass, 8.0 x 7.0 x 5.0 cm in greatest dimension. The outer surface displays multiple nodules as well as an adhered fallopian tube segment with delicate fimbria, 7.0 cm in length and 0.4 cm in diameter. Sectioning reveals serous fluid filled cystic cavity of the dimensions displaying gray-yellow papillary projections of the inner lining of the cyst wall in an area 4.0 x 3.0 x 1.5 cm. Samples of this tissue are submitted for frozen section. Representative samples submitted in seven cassettes which are designated as follows: frozen section tissue--1; fallopian tube--2; multiple samples cyst wall--3 to 7. A total of five blocks are submitted for genomic research from part A.

B. Container B is labeled [redacted] and consists of a tan-yellow soft nodule, 1.0 x 1.0 x 0.5 cm. It is bisected and entirely submitted in one cassette.

C. Container C is labeled [redacted] and consists of a 47 gram uterus, 6.0 x 3.5 x 2.5 cm in greatest dimension. The serosal surface is tan-orange fibrous hemorrhagic displaying a few adhesions. The cervix is covered by a tan-gray glistening mucosa with a central patent os, 0.3 cm in diameter. The endocervical canal is tan-pink slightly roughened. The endometrial cavity is lined by tan-pink focally hemorrhagic mucosa, 0.2 cm in thickness. The myometrium averages 1.6 cm is indurated displaying gray-white whorled nodules, 0.5 cm in diameter. Samples of the right and left parametrium are submitted. The right parametrium is inked.

Attached is the right ovary and fallopian tube segment. The ovary is tan-yellow nodular hemorrhagic, 3.8 x 3.0 x 2.8 cm in greatest dimension displaying multiple adhesions. Sectioning reveals a tan-yellow lobular firm cut surface. Attached on the outer surface is a tan-gray fallopian tube segment with delicate fimbria, 6.0 cm in length and 0.4 cm in diameter displaying multiple adhesion.

Samples of the uterus have been submitted for genomic studies in three orange cassettes.

Representative samples submitted in twelve cassettes which are designated as follows: anterior cervix--1; posterior cervix--2; anterior myometrium--3 and 4; posterior myometrium--5 and 6; whorled nodules--7; right and left parametrium--8; ovary and fallopian tube--9 to 12.

Following initial evaluation of the specimen microscopically, the remainder of the endometrium was blocked in C13-18.

D. Container D is labeled [redacted] and consists of a tan-yellow lobular mass of adipose tissue, 1.0 x 0.8 x 0.5 cm in greatest dimension entirely submitted in one cassette.

E. Container E is labeled [redacted] and consists of a tan-yellow rubbery firm nodule, 0.8 x 0.8 x 0.5 cm. The specimen is bisected and entirely submitted in one cassette.

[page 2 of 3]
from [REDACTED]

F. Container F is labeled [REDACTED] and consists of multiple tan-yellow lobular portions of adipose tissue, 4.0 x 3.0 x 3.0 cm in aggregate. Sectioning reveals five tan-yellow firm rubbery nodules, the largest 1.4 cm in greatest dimension. Samples of these five nodules are submitted in two cassettes.

G. Container G is labeled [REDACTED] and consists of multiple tan-yellow lobular portions of adipose tissue, 6.0 x 4.0 x 3.0 cm in aggregate. Sectioning reveals four tan-yellow firm fatty lymph nodes, the largest 2.8 cm in greatest dimension. Samples of these nodes are submitted in three cassettes.

H. Container H is labeled [REDACTED] and consists of a tan-yellow lobular mass of adipose tissue, 2.4 x 1.0 x 1.0 cm in greatest dimension. Sectioning reveals two tan-yellow firm nodules, the largest 0.8 cm. Samples are submitted in one cassette.

I. Container I is labeled [REDACTED] and consists of a 288 gram mass of tan-yellow lobular omentum, 36.0 x 15.0 x 1.5 cm in greatest dimension. Sectioning reveals multiple yellow-white firm nodules, the largest 3.5 cm in greatest dimension. These nodules represent less than 10% of the omentum. Representative samples submitted in four cassettes.

J. Container J is labeled [REDACTED] and consists of a purple-pink rubbery mass of membranous tissue, 3.8 x 1.8 x 1.0 cm in greatest dimension. Sectioning reveals a tan-yellow lobular firm cut surface. No lesions are grossly identified. Representative samples submitted in one cassette.

[page 3 of 3]
DIAGNOSIS:

- 1. Ovary and fallopian tube, left, excision with frozen section:
- Papillary serous carcinoma of the ovary.
- Grade: 3/3.
- Degree of ovarian involvement: Ovary replaced.
- Size: 8.0 x 7.0 x 5.0 cm.
- Lymphovascular space invasion: Absent.
- Left fallopian tube: Uninvolved by neoplasm.
- Frozen section results confirmed.
- 2. Soft tissue, pelvis, excision:
- Nodular necrotic adipose tissue, consistent with torted appendix epiploica.
- 3. Uterus, cervix, excision:
- No pathologic alterations.
- Uterus, endometrium, excision:
- Adenocarcinoma, grade 3/3, 1.5 mm nodule confined to endometrium.
- Cystic atrophy, diffuse.
- Atrophic polyp.
- Uterus, myometrium, excision:
- Adenomyosis with atrophic changes.
- Leiomyomata.
- Uterus, serosa, excision:
- No pathologic alterations.
- Soft tissue, parametrial, excision:
- Adenocarcinoma, metastatic.
- Fallopian tube, right, excision:
- No pathologic alterations.
- Ovary, right, excision:
- Papillary serous carcinoma.
- 1. Grade: 3/3.
- 2. Degree of involvement: Replaces approximately 80% of ovary.
- 3. Size: 3.8 x 3.0 x 2.8 cm.
- 4. Lymphovascular space invasion: Absent.
- D. Soft tissue, left pelvic, biopsy:
- No pathologic alterations.
- No lymph nodes identified.
- E. Lymph nodes, left para-aortic, regional resection:
- No pathologic alterations, free of metastatic neoplasm, two lymph nodes examined.
- F. Lymph nodes, left pelvic, regional resection:
- No pathologic alterations, free of metastatic neoplasm, six lymph nodes examined.
- G. Lymph nodes, right pelvic, regional resection:
- No pathologic alterations, free of metastatic neoplasm, eight lymph nodes examined.
- H. Lymph nodes, right para-aortic, regional resection:
- No pathologic alterations, free of metastatic neoplasm, five lymph nodes examined.
- I. Omentum, excision:
- Papillary serous carcinoma, metastatic.
- Nodules grossly identified, up to 3.5 cm.
- J. Soft tissue, abdominal wall, excision:

Source: NCI Genomic Data Commons file 5aebfc05-f143-4b0e-a06a-d01592777323 (TCGA-57-1994.54C3DD01-B473-424F-987A-C5D6E972E9BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).